Somatic mutation profile of tumor specimen TCGA-K4-A3WS-01A (aliquot TCGA-K4-A3WS-01A-11D-A22Z-08) from TCGA case TCGA-K4-A3WS, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 66.0 years (24,124 days).
Specimen TCGA-K4-A3WS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44c30b2f-7023-4e95-8dc3-39f393d2324c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K4-A3WS-10A (Blood Derived Normal), aliquot TCGA-K4-A3WS-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c07ab382-b15e-4466-9d0b-ecb0966c0852

The open-access MAF lists 316 somatic variants for this specimen: 242 protein-altering or splice-affecting, 63 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 206, Silent 63, Nonsense Mutation 22, Frame Shift Del 6, Splice Site 4, Intron 4, In Frame Del 2, RNA 2, 5'Flank 2, 5'UTR 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.8608C>T p.Q2870* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as rs587782010, COSV66463224; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.574A>T p.N192Y | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52629566; called by muse, mutect2
- ACSS3 | c.2041G>T p.E681* | Nonsense Mutation (SNP) | VAF 9/79 reads (11%) | catalogued as COSV54091590; called by muse, mutect2, varscan2
- ACVR1B | c.1066C>G p.L356V | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV57778596; called by muse, mutect2
- AFAP1L1 | c.1212G>C p.K404N | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57046552, COSV99695763; called by muse, mutect2
- AHNAK | c.14563G>T p.D4855Y | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57222291; called by muse, mutect2, varscan2
- AKAP3 | c.2332C>T p.Q778* | Nonsense Mutation (SNP) | VAF 5/78 reads (6%) | catalogued as COSV99962309; called by muse, mutect2
- ALDOB | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100878863; called by muse, mutect2
- ALYREF | c.641G>C p.G214A | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as COSV58668831; called by muse, mutect2, varscan2
- AMZ2 | c.357C>G p.F119L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV63083492; called by muse, mutect2, varscan2
- ANK3 | c.7768G>A p.E2590K | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV55057411, COSV99778550; called by muse, mutect2, varscan2
- ANKFY1 | c.2696C>T p.S899L (on ENST00000341657 / NM_001330063.2; = p.S900L on NM_016376.5) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV58919774; called by muse, varscan2
- ANKRD26 | c.147G>C p.K49N | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV65796638; called by muse, mutect2, varscan2
- ANKRD27 | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs934075569, COSV60133761; called by muse, mutect2
- AP4E1 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV55918593; called by muse, mutect2, varscan2
- ARID2 | c.1885G>C p.D629H | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV57609791; called by muse, mutect2, varscan2
- ARL13B | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.488); catalogued as COSV57399983; called by muse, mutect2, varscan2
- ARPC4 | c.432G>C p.K144N | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV55029063; called by muse, mutect2
- ATM | c.6491A>G p.E2164G | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM121266, COSV53759169; called by muse, mutect2, varscan2
- ATP13A5 | c.2860C>G p.H954D | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV60872120; called by muse, mutect2
- ATP2B2 | c.1115A>G p.K372R (on ENST00000352432; = p.K338R on NM_001683.5) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV59494517, COSV59502626; called by muse, mutect2, varscan2
- BABAM1 | c.344G>C p.G115A | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.731); catalogued as COSV63921060, COSV63921216; called by muse, mutect2, varscan2
- BCL9 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs201495777, COSV52347526; called by muse, mutect2
- BPIFB3 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV64957751; called by muse, mutect2, varscan2
- BRCA1 | c.5290C>A p.L1764I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV58794928; called by muse, mutect2, varscan2
- C12orf54 | c.87G>C p.M29I | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100011684, COSV58360617; called by muse, mutect2, varscan2
- C1orf116 | c.75G>T p.M25I | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs1558046270, COSV63944390; called by muse, mutect2, varscan2
- C5orf24 | c.523G>T p.G175W | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); catalogued as COSV57543124; called by muse, mutect2
- CACNA1E | c.5726A>T p.Q1909L | Missense Mutation (SNP) | VAF 21/301 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV62406732; called by muse, mutect2
- CALD1 | c.1866G>A p.M622I (on ENST00000361675 / NM_033138.4; = p.M367I on NM_004342.7) | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV62650700; called by muse, mutect2
- CC2D1A | c.2083C>G p.Q695E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV58784876; called by muse, mutect2, varscan2
- CD33 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51803233; called by muse, mutect2, varscan2
- CDC37L1 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.143); catalogued as COSV67866156; called by muse, mutect2, varscan2
- CEACAM7 | c.29G>C p.R10T | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.967); catalogued as COSV50073768; called by muse, mutect2, varscan2
- CHD6 | c.6104G>C p.R2035T | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV64692768; called by muse, mutect2, varscan2
- CHD6 | c.4384G>A p.V1462M | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64692769; called by muse, mutect2
- CHD7 | c.6908G>A p.R2303K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0.428); catalogued as COSV101417921, COSV71112854; called by muse, mutect2, varscan2
- CIAO3 | c.422C>G p.S141* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as rs768755961; called by muse, mutect2, varscan2
- CKAP5 | c.5653C>G p.R1885G (on ENST00000529230 / NM_001008938.4; = p.R1825G on NM_014756.3) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56371042; called by muse, mutect2, varscan2
- CLDN5 | c.631G>A p.D211N (on ENST00000618236 / NM_001363066.2; = p.D296N on NM_003277.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.261); catalogued as COSV54246985; called by mutect2, varscan2
- CSF1R | c.2731C>G p.Q911E | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.163); catalogued as COSV53833640, COSV53839185; called by muse, mutect2, varscan2
- CUX2 | c.3517G>T p.V1173L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55640224, COSV99919668; called by muse, mutect2, varscan2
- DAOA | c.222G>C p.Q74H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as COSV61602122, COSV61603077; called by muse, mutect2, varscan2
- DCAF12L2 | c.1060C>G p.R354G | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV63583106; called by muse, mutect2, varscan2
- DDX20 | c.1450C>G p.Q484E | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs778879441, COSV63780263; called by muse, mutect2, varscan2
- DDX4 | c.510C>A p.D170E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61756137; called by muse, mutect2, varscan2
- DENND5B | c.2938A>T p.M980L | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV60905520; called by muse, mutect2
- DMGDH | c.102-1G>C p.X34_splice | Splice Site (SNP) | VAF 14/69 reads (20%) | catalogued as COSV54864922; called by muse, mutect2, varscan2
- DNAJC5B | c.74G>C p.G25A | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV52538579; called by muse, mutect2, varscan2
- DNASE2B | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs146223730; called by muse, mutect2, varscan2
- DNM2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV58967188; called by muse, mutect2, varscan2
- DOP1A | c.1463G>C p.R488T | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs770977084, COSV52713831; called by mutect2, varscan2
- DOP1A | c.5842C>A p.L1948M | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99381789; called by muse, mutect2
- DPPA4 | c.830C>A p.P277Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59509498, COSV59511688; called by muse, mutect2, varscan2
- DTX2 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV56863142; called by muse, mutect2, varscan2
- ECHDC3 | c.236A>C p.Q79P | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.563); catalogued as COSV64867744; called by muse, mutect2, varscan2
- ELANE | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as rs759382746, COSV55048623; called by muse, mutect2, varscan2
- FAM167B | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV61110131; called by muse, mutect2, varscan2
- FAT1 | c.11120C>A p.S3707* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV71672121; called by muse, mutect2, varscan2
- FAT2 | c.10855G>T p.V3619L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV55822890, COSV55824857; called by muse, mutect2, varscan2
- FAU | c.26A>T p.E9V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.508); catalogued as COSV54195496; called by muse, mutect2, varscan2
- FBLN7 | c.1129G>T p.G377C | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55616795; called by muse, mutect2
- FBXO31 | c.1300G>T p.A434S | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV100291403; called by muse, mutect2
- FCRL3 | c.428G>C p.S143T | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.06); catalogued as COSV63843381; called by muse, mutect2, varscan2
- FCRL5 | c.753G>C p.W251C | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV62517487; called by muse, mutect2
- FRY | c.8107A>C p.T2703P | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV66574459; called by muse, mutect2, varscan2
- GDA | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV52994961, COSV52995621; called by muse, mutect2, varscan2
- GNA13 | c.598A>G p.R200G | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV71474990; called by muse, mutect2, varscan2
- GRIA2 | c.2455A>G p.I819V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1461547840, COSV52398287; called by muse, mutect2, varscan2
- GRID1 | c.181A>G p.T61A | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); catalogued as COSV60040976; called by muse, mutect2, varscan2
- GRM1 | c.2872G>C p.E958Q | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV51203718; called by muse, mutect2, varscan2
- GYS2 | c.1778C>T p.S593L | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53926120; called by muse, mutect2, varscan2
- H6PD | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.354); catalogued as COSV66231585; called by muse, mutect2
- HIGD1C | c.75C>A p.D25E | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.306); catalogued as COSV68250744; called by muse, mutect2, varscan2
- HSPBAP1 | c.1062G>T p.M354I | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV60243044; called by muse, mutect2
- HTN1 | c.74G>A p.R25K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as COSV55895182, COSV99887588; called by muse, mutect2, varscan2
- IGHMBP2 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54824291; called by muse, mutect2, varscan2
- IL13RA1 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV65424810; called by muse, mutect2, varscan2
- INTS6 | c.1673G>C p.R558T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60879465; called by muse, mutect2, varscan2
- IPO8 | c.621C>G p.I207M | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56243690; called by muse, mutect2, varscan2
- IRF6 | c.23T>A p.V8D | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65419857; called by muse, mutect2, varscan2
- ITGB1BP2 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV52139045; called by muse, mutect2, varscan2
- KALRN | c.4523G>A p.S1508N | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53773258; called by muse, mutect2, varscan2
- KCNB1 | c.1595T>G p.M532R | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as COSV65569733; called by muse, mutect2
- KCNU1 | c.2003C>A p.T668N | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV67758100; called by muse, mutect2, varscan2
- KDR | c.2875C>G p.L959V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.151); catalogued as COSV55771078; called by muse, mutect2, varscan2
- KHDRBS1 | c.1033C>G p.P345A | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV56982831; called by muse, mutect2
- KIAA1549 | c.5390G>C p.R1797T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779399463, COSV54321333; called by mutect2, varscan2
- KMT2D | c.2485G>C p.E829Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV56464366, COSV99040336; called by muse, mutect2, varscan2
- KRTAP27-1 | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV67001433; called by muse, mutect2, varscan2
- LPIN2 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV55241930; called by muse, mutect2, varscan2
- LTBP2 | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV100000404, COSV56211108, COSV56214780; called by muse, mutect2
- LY9 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as COSV54435922; called by muse, mutect2, varscan2
- MAB21L1 | c.835T>C p.S279P | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as COSV59803763; called by muse, mutect2, varscan2
- MAIP1 | c.419G>A p.S140N | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as COSV54461147; called by muse, mutect2, varscan2
- MAML2 | c.2782G>T p.G928* | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | catalogued as COSV73262875; called by muse, mutect2, varscan2
- MCF2L2 | c.848A>T p.N283I | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV61057226, COSV61057754; called by muse, mutect2, varscan2
- MCM3AP | c.1927G>C p.E643Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52442180, COSV52442710; called by muse, mutect2, varscan2
- MED1 | c.205C>A p.L69I | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.883); catalogued as COSV56127107; called by muse, mutect2, varscan2
- MED17 | c.1498G>C p.E500Q | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV52602105; called by muse, mutect2, varscan2
- MOB3C | c.204C>G p.F68L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54719851; called by muse, mutect2, varscan2
- MPP6 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV56040703; called by muse, mutect2, varscan2
- MYC | c.21C>A p.F7L (on ENST00000377970; = p.F22L on NM_002467.6) | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52369158, COSV52374846; called by muse, mutect2, varscan2
- MYLK | c.1432C>G p.R478G | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV60615910; called by mutect2, varscan2
- NFE2L2 | c.1799C>G p.P600R | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV67961723; called by muse, mutect2
- NINL | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.084); catalogued as COSV54005832; called by muse, mutect2, varscan2
- NIPSNAP1 | c.226+1G>T p.X76_splice | Splice Site (SNP) | VAF 8/45 reads (18%) | catalogued as COSV53343347; called by muse, mutect2, varscan2
- NKAIN2 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV63676164; called by muse, mutect2, varscan2
- NOM1 | c.679A>G p.K227E | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV51979717; called by muse, mutect2, varscan2
- NPAP1 | c.1459G>T p.V487F | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV61509060; called by muse, mutect2, varscan2
- NUAK2 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as COSV65682063; called by muse, mutect2, varscan2
- OAS2 | c.1685C>G p.S562C | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60803476; called by muse, mutect2, varscan2
- OCLN | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV62285705; called by muse, mutect2, varscan2
- OR7C1 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as COSV50183726; called by muse, mutect2, varscan2
- OR8B4 | c.664T>C p.S222P | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV62070184; called by muse, mutect2, varscan2
- OSBPL11 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.061); catalogued as COSV56175246; called by muse, mutect2, varscan2
- P2RX3 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.16); catalogued as COSV54443708; called by muse, mutect2, varscan2
- PAPPA | c.1265A>G p.E422G | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV60287924; called by muse, mutect2, varscan2
- PARP14 | c.2801T>G p.V934G | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV71735192; called by muse, mutect2, varscan2
- PCDH15 | c.212C>G p.P71R | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.96); PolyPhen benign (0.019); catalogued as COSV57353276; called by muse, mutect2
- PCIF1 | c.1263G>C p.M421I | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV59818913; called by muse, mutect2
- PEG3 | c.341G>C p.C114S | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55640701; called by muse, mutect2
- PELI2 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV50709972, COSV50713135; called by muse, mutect2, varscan2
- PES1 | c.426C>G p.F142L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV58829225, COSV58829664; called by muse, mutect2, varscan2
- PEX19 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV63619897; called by muse, mutect2, varscan2
- PIGR | c.742G>C p.D248H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV62904590; called by muse, mutect2, varscan2
- PISD | c.164C>G p.T55S | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.503); catalogued as COSV60673824; called by muse, mutect2, varscan2
- PLEKHA7 | c.239C>G p.T80R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63048615; called by muse, mutect2, varscan2
- POSTN | c.1709G>C p.G570A | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as COSV65713788; called by muse, mutect2, varscan2
- PRKG1 | c.1758G>C p.L586F | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64774420; called by muse, mutect2
- PRL | c.88C>G p.P30A | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV60592971; called by muse, mutect2, varscan2
- PROX1 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54781423; called by muse, mutect2, varscan2
- PRR14 | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV54912814; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1387G>C p.E463Q (on ENST00000421990 / NM_001136042.2; = p.E445Q on NM_025267.3) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as COSV64182771; called by muse, mutect2, varscan2
- RAB3GAP1 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV51485277; called by muse, mutect2, varscan2
- RAD21 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV52061474; called by muse, mutect2, varscan2
- RAD51D | c.980A>C p.Q327P | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV60005564; called by muse, mutect2, varscan2
- RARG | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV58433927; called by muse, varscan2
- RARRES1 | c.396C>G p.F132L | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1321884163, COSV52963143; called by muse, mutect2, varscan2
- RASAL2 | c.2497G>T p.D833Y | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62718212; called by muse, mutect2, varscan2
- RASSF3 | c.599_608del p.N200Tfs*14 | Frame Shift Del (DEL) | VAF 14/87 reads (16%) | catalogued as COSV51686395; called by mutect2, pindel, varscan2
- RBBP7 | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs142056030, COSV66301188; called by muse, mutect2
- RIN2 | c.2384C>G p.S795C (on ENST00000255006 / NM_001242581.1; = p.S746C on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54791139, COSV99657208, COSV99657631; called by muse, mutect2, varscan2
- RNF113B | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1566701927, COSV57435546; called by muse, mutect2, varscan2
- ROPN1 | c.546G>T p.R182S | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.962); catalogued as COSV51740555; called by muse, mutect2
- RPL6 | c.258G>C p.E86D | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV52517529; called by muse, mutect2, varscan2
- SAMD4B | c.707C>G p.S236C | Missense Mutation (SNP) | VAF 23/289 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58752473; called by muse, mutect2
- SCN1A | c.2440G>A p.E814K (on ENST00000303395 / NM_001202435.3; = p.E803K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV57675020; called by muse, mutect2, varscan2
- SEMG2 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV101034103, COSV65647725; called by muse, mutect2
- SEPTIN8 | c.689T>A p.V230D | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.345); catalogued as COSV51524593; called by muse, mutect2, varscan2
- SFRP4 | c.933T>A p.S311R | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as COSV71412466; called by muse, mutect2, varscan2
- SH2D3C | c.1294C>A p.P432T (on ENST00000314830 / NM_170600.3; = p.P275T on NM_005489.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV59122436, COSV59126748; called by muse, mutect2, varscan2
- SIM1 | c.1775T>A p.L592Q | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV53494481; called by muse, mutect2, varscan2
- SLAMF9 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV63636989; called by muse, mutect2
- SLC14A1 | c.937C>T p.L313F | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58933185, COSV58934734; called by muse, mutect2, varscan2
- SLC35B2 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV51490819; called by muse, mutect2, varscan2
- SLC6A11 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.326); catalogued as rs1269132853; called by muse, mutect2
- SLC7A1 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV66331118; called by muse, mutect2, varscan2
- SMARCA1 | c.2359C>T p.Q787* | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | catalogued as COSV64410750; called by muse, mutect2, varscan2
- SPECC1L | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58660009; called by muse, mutect2, varscan2
- STRBP | c.1656C>G p.F552L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62119259; called by muse, mutect2, varscan2
- SUN5 | c.866T>A p.L289Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV62181824; called by muse, mutect2
- TAS2R1 | c.726G>T p.M242I | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV66779042; called by muse, mutect2, varscan2
- TBC1D32 | c.2219C>G p.A740G | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV51548634; called by muse, mutect2, varscan2
- TEK | c.1643G>C p.G548A | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV66230971; called by muse, mutect2, varscan2
- TG | c.5014G>A p.D1672N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV55086220; called by muse, mutect2, varscan2
- THBS3 | c.1566C>A p.F522L | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV64250314; called by muse, mutect2
- THSD7B | c.4247G>T p.S1416I (on ENST00000272643; = p.S1414I on NM_001316349.2) | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.462); catalogued as COSV55713290; called by muse, mutect2, varscan2
- TIAM2 | c.2600C>T p.P867L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as COSV59698597; called by muse, mutect2, varscan2
- TINAGL1 | c.1094-1G>A p.X365_splice | Splice Site (SNP) | VAF 5/25 reads (20%) | catalogued as COSV54699557; called by muse, mutect2, varscan2
- TNN | c.1148T>A p.L383Q | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53430743; called by muse, mutect2
- TNN | c.2613C>A p.N871K | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.027); catalogued as COSV53430753; called by muse, mutect2
- TOM1 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV65898792; called by muse, mutect2, varscan2
- TP53BP1 | c.2926G>A p.G976R | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.255); catalogued as COSV55505069, COSV55508806; called by muse, mutect2, varscan2
- TRIO | c.4498T>G p.L1500V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV60088672; called by muse, mutect2, varscan2
- TRIOBP | c.2001C>G p.I667M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as COSV60381222; called by muse, mutect2, varscan2
- TSBP1 | c.1418C>T p.S473L (on ENST00000617061; = p.S478L on NM_006781.5) | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV66660100; called by muse, mutect2
- TTK | c.1960C>G p.L654V | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.177); catalogued as COSV57885279; called by muse, mutect2
- TTN | c.87535A>T p.N29179Y (on ENST00000591111; = p.N21755Y on NM_003319.4) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | PolyPhen benign (0.106); catalogued as COSV60199705; called by muse, mutect2, varscan2
- TUT7 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.257); catalogued as COSV52897278; called by muse, mutect2
- UCKL1 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.162); catalogued as rs369768152; called by muse, mutect2, varscan2
- USH1G | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.535); catalogued as rs746328214, COSV58882793; called by muse, mutect2, varscan2
- VARS2 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as rs1435047139; called by muse, mutect2
- VPS16 | c.991C>A p.P331T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66796976; called by muse, mutect2, varscan2
- VSIG2 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV52519046; called by muse, mutect2, varscan2
- VTI1B | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV53620358; called by muse, mutect2, varscan2
- WDR26 | c.1418G>C p.G473A (on ENST00000414423 / NM_001379403.1; = p.G373A on NM_025160.7) | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.199); catalogued as COSV54357916; called by muse, mutect2
- WFDC13 | c.73A>C p.K25Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.929); catalogued as COSV57914426; called by muse, mutect2, varscan2
- WT1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV60065484, COSV60073094, COSV60074839, COSV60076810; called by muse, mutect2, varscan2
- XDH | c.3848G>C p.R1283P | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764753696, COSV65150112; called by muse, mutect2, varscan2
- XIRP1 | c.5122G>A p.A1708T | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV61139841; called by muse, mutect2, varscan2
- YLPM1 | c.569C>G p.S190C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.923); catalogued as COSV53116544; called by muse, mutect2, varscan2
- ZC3H18 | c.28G>C p.D10H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.366); catalogued as COSV56326386; called by muse, mutect2, varscan2
- ZNF146 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61932289; called by muse, mutect2, varscan2
- ZNF223 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV71571987; called by muse, mutect2
- ZNF37A | c.1639G>C p.G547R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.279); catalogued as COSV61074535; called by muse, mutect2, varscan2
- ZNF43 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.631); catalogued as COSV61683460, COSV61684890; called by muse, mutect2
- ZNF502 | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV56074392; called by muse, mutect2, varscan2
- ZNF518A | c.3534G>C p.Q1178H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1270814280; called by muse, mutect2, varscan2
- ZNF607 | c.1593A>C p.K531N | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62205893; called by muse, mutect2, varscan2
- ZNF641 | c.1016A>G p.Q339R | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.909); catalogued as COSV56391040; called by muse, mutect2, varscan2
- ZSCAN25 | c.943G>C p.G315R | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV53553824; called by muse, mutect2, varscan2
- ZSCAN5B | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs775303355, COSV62000658; called by muse, mutect2, varscan2
- ACACA | c.3157G>C p.E1053Q | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADAMTS5 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2
- ANKFY1 | c.2638C>T p.Q880* (on ENST00000341657 / NM_001330063.2; = p.Q881* on NM_016376.5) | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | called by muse, varscan2
- ATF6 | c.1805-1G>A p.X602_splice | Splice Site (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- ATXN3 | c.926C>A p.S309* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- BIRC6 | c.11302C>G p.L3768V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.765); called by muse, mutect2
- BTBD7 | c.3007G>T p.E1003* | Nonsense Mutation (SNP) | VAF 61/152 reads (40%) | called by muse, mutect2, varscan2
- CCDC9 | c.1034G>C p.R345T | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2
- CHIT1 | c.830C>A p.S277* | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- CRY1 | c.860dup p.Y287* | Nonsense Mutation (INS) | VAF 18/72 reads (25%) | called by mutect2, pindel*, varscan2
- CSPG5 | c.1597G>T p.E533* (on ENST00000383738 / NM_001206943.2; = p.E506* on NM_006574.4) | Nonsense Mutation (SNP) | VAF 19/101 reads (19%) | called by muse, mutect2, varscan2
- EDA | c.1175A>G p.*392Wext*29 | Nonstop Mutation (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- GCC2 | c.1141dup p.E381Gfs*6 | Frame Shift Ins (INS) | VAF 31/117 reads (26%) | called by mutect2, pindel, varscan2
- HDAC4 | c.3084_3096del p.W1028Cfs*11 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by mutect2, pindel, varscan2
- IFNLR1 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- IVL | c.1654_1672del p.V552Pfs*12 | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel
- KCNJ16 | c.813_828del p.A272Rfs*4 | Frame Shift Del (DEL) | VAF 12/153 reads (8%) | called by mutect2, pindel
- MCCC2 | c.913_935del p.E305Sfs*3 | Frame Shift Del (DEL) | VAF 6/78 reads (8%) | called by mutect2, pindel
- MPI | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- MRM1 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.897); called by muse, mutect2
- NAT8 | c.419_438del p.F140* | Frame Shift Del (DEL) | VAF 14/93 reads (15%) | called by mutect2, pindel
- NCAN | c.2837C>G p.S946* | Nonsense Mutation (SNP) | VAF 17/158 reads (11%) | called by muse, mutect2, varscan2
- NDUFAF1 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- NFIA | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PSD3 | c.2944G>T p.E982* (on ENST00000440756; = p.E981* on NM_015310.4) | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- RPTOR | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SAMD4B | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2
- SELENBP1 | c.1173G>C p.Q391H | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SEMA3B | c.1188C>A p.D396E | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC6A20 | c.752C>G p.S251* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- TAS2R14 | c.379_393del p.K127_L131del | In Frame Del (DEL) | VAF 7/78 reads (9%) | called by mutect2, pindel
- TKTL1 | c.622A>T p.K208* | Nonsense Mutation (SNP) | VAF 25/114 reads (22%) | called by muse, mutect2, varscan2
- TLK2 | c.596A>G p.K199R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TP53BP2 | c.412C>T p.Q138* (on ENST00000343537 / NM_001031685.3; = p.Q9* on NM_005426.2) | Nonsense Mutation (SNP) | VAF 37/116 reads (32%) | called by muse, mutect2, varscan2
- TRAF3IP1 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- TRMT1L | c.778C>G p.R260G | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TTI1 | c.1012G>T p.G338* | Nonsense Mutation (SNP) | VAF 29/202 reads (14%) | called by muse, mutect2, varscan2
- TXNDC15 | c.145_153del p.A49_P51del | In Frame Del (DEL) | VAF 6/42 reads (14%) | called by pindel, varscan2
- ABCA13 | c.3405C>A p.V1135= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV70036541; called by muse, mutect2, varscan2
- ABCG5 | c.1221C>G p.V407= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV53212041; called by muse, mutect2, varscan2
- ABHD1 | c.121C>A p.R41= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV53207241; called by muse, mutect2, varscan2
- ACAN | c.1647G>A p.K549= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV61365012; called by muse, mutect2, varscan2
- AGO4 | c.1635G>A p.V545= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV64617900; called by muse, varscan2
- AKAP13 | c.7242T>A p.A2414= (on ENST00000394518 / NM_007200.5; = p.A2418= on NM_006738.6) | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV63464647; called by muse, mutect2, varscan2
- ARID2 | c.3528T>C p.V1176= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV57609801; called by muse, mutect2, varscan2
- ASTN1 | c.276C>T p.F92= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs762270867, COSV56072638; called by muse, mutect2
- ATP6V0D1 | c.69G>A p.L23= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV52099000; called by muse, mutect2, varscan2
- BCAS4 | c.594C>G p.T198= | Silent (SNP) | VAF 17/134 reads (13%) | catalogued as COSV52813228; called by muse, mutect2, varscan2
- BRPF3 | c.117G>A p.R39= | Silent (SNP) | VAF 4/74 reads (5%) | catalogued as COSV60206408; called by muse, mutect2
- CALR3 | c.366G>A p.L122= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV54171026; called by muse, mutect2, varscan2
- CASKIN2 | c.2412T>A p.P804= | Silent (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- CBL | c.468C>T p.L156= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV50648182; called by muse, mutect2, varscan2
- CCDC85A | c.1524A>G p.G508= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV68153721, COSV68154470; called by muse, mutect2, varscan2
- CCL27 | c.126C>G p.L42= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV52405333; called by muse, mutect2, varscan2
- CD207 | c.930A>G p.P310= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV69652392; called by muse, mutect2, varscan2
- CHAT | c.1215C>G p.L405= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV60328974; called by muse, mutect2, varscan2
- CNTN2 | c.258C>T p.S86= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV59351543; called by muse, varscan2
- CPSF1 | c.1299G>A p.A433= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs534194187, COSV100574390, COSV62941365; called by muse, mutect2, varscan2
- CPTP | c.345G>A p.L115= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- CRISP2 | c.366C>T p.V122= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV59253308, COSV59255751; called by muse, mutect2, varscan2
- DAXX | c.810C>T p.R270= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as COSV56471351; called by muse, mutect2, varscan2
- DLGAP4 | c.1107C>T p.Y369= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- DNAH1 | c.5721G>T p.T1907= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs200419197; called by muse, mutect2, varscan2
- DUT | c.483G>A p.A161= (on ENST00000331200 / NM_001025248.2; = p.A73= on NM_001948.4) | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs201357294; called by muse, mutect2, varscan2
- ESPL1 | c.2379G>A p.L793= | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as COSV57761082; called by muse, mutect2, varscan2
- EVPL | c.3555G>A p.K1185= | Silent (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- FAH | c.861G>T p.L287= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV55722571; called by muse, mutect2, varscan2
- FH | c.1188C>A p.V396= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV63818592; called by muse, mutect2, varscan2
- FMO3 | c.303G>A p.L101= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV63006441; called by muse, mutect2, varscan2
- G6PC | c.981C>T p.F327= | Silent (SNP) | VAF 12/139 reads (9%) | catalogued as COSV53831807; called by muse, mutect2
- GARRE1 | c.1023C>G p.T341= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as COSV55101568; called by muse, mutect2, varscan2
- IL13RA1 | c.528C>T p.I176= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV65426677; called by muse, mutect2, varscan2
- KCNU1 | c.2004C>G p.T668= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV67758106; called by muse, mutect2
- KIR3DL2 | c.717C>T p.N239= | Silent (SNP) | VAF 101/243 reads (42%) | catalogued as rs1291644730; called by muse, varscan2
- KIRREL1 | c.1125G>T p.V375= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV63289497; called by muse, mutect2, varscan2
- KRTAP10-7 | c.588C>T p.C196= | Silent (SNP) | VAF 25/158 reads (16%) | catalogued as rs782483881, COSV100170128; called by muse, mutect2, varscan2
- LAMP5 | c.168G>C p.T56= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV55715725; called by muse, mutect2
- MFSD12 | c.672G>T p.V224= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- MUC17 | c.1200C>G p.V400= | Silent (SNP) | VAF 105/344 reads (31%) | catalogued as COSV60279755, COSV60296183; called by muse, mutect2, varscan2
- MYLK2 | c.1659C>T p.R553= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs727504624, COSV65659533; called by mutect2, varscan2
- NOP9 | c.198C>T p.R66= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV55385093; called by muse, mutect2, varscan2
- OR14K1 | c.802C>T p.L268= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV51721711, COSV51721938; called by muse, mutect2, varscan2
- OTOF | c.1968G>A p.R656= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV55510552, COSV55525476; called by muse, mutect2, varscan2
- PAWR | c.940C>T p.L314= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV60923831; called by muse, mutect2, varscan2
- PCDHGB1 | c.1773C>T p.D591= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV99537627; called by muse, mutect2, varscan2
- PKN3 | c.1077C>T p.V359= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV52578270; called by muse, mutect2, varscan2
- PPP1R8 | c.963C>G p.V321= (on ENST00000311772 / NM_014110.5; = p.V97= on NM_002713.4) | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as COSV52580660; called by muse, mutect2
- PPP2R5D | c.349C>T p.L117= | Silent (SNP) | VAF 27/191 reads (14%) | catalogued as COSV57840888; called by muse, mutect2, varscan2
- RIPOR1 | c.2676C>T p.L892= (on ENST00000379312 / NM_001193522.2; = p.L888= on NM_024519.4) | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV50237882; called by muse, mutect2, varscan2
- SACS | c.13326C>A p.G4442= | Silent (SNP) | VAF 33/147 reads (22%) | catalogued as COSV66544029; called by muse, mutect2, varscan2
- SIM2 | c.679C>T p.L227= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV51770907; called by muse, mutect2, varscan2
- SLC25A24 | c.1269A>G p.P423= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV51449170; called by muse, mutect2, varscan2
- SPPL2C | c.1587G>A p.Q529= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV61293196; called by muse, mutect2, varscan2
- ST3GAL1 | c.717G>A p.V239= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV60614983; called by muse, mutect2, varscan2
- TAF2 | c.2328A>G p.L776= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs771001599; called by muse, mutect2
- TCP1 | c.630C>T p.L210= | Silent (SNP) | VAF 10/153 reads (7%) | catalogued as rs377216804, COSV58459746; called by muse, mutect2
- TDRD7 | c.2811G>A p.K937= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV62430312; called by muse, mutect2
- TIMM50 | c.582G>A p.T194= | Silent (SNP) | VAF 32/258 reads (12%) | catalogued as rs62120692, COSV58678631; called by muse, mutect2, varscan2
- TKTL1 | c.621C>T p.H207= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as COSV54213892, COSV99474280; called by muse, mutect2, varscan2
- UNC13B | c.3159C>T p.V1053= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs150684985, COSV65931915; called by muse, mutect2, varscan2
- VCAN | c.6600T>A p.T2200= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as COSV54110925; called by muse, mutect2, varscan2
- CD300LD | c.-16G>T | 5'UTR (SNP) | VAF 18/72 reads (25%) | catalogued as rs1452964309, COSV60084297; called by muse, mutect2, varscan2
- CD300LD | c.-17G>C | 5'UTR (SNP) | VAF 18/72 reads (25%) | catalogued as COSV60084303; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055638 C>G | 3'Flank (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- H3-3B | chr17:75784737 G>A | 5'Flank (SNP) | VAF 3/25 reads (12%) | catalogued as COSV53141789; called by muse, mutect2
- MACF1 | c.15832-12042G>T | Intron (SNP) | VAF 8/44 reads (18%) | catalogued as COSV57109215; called by muse, mutect2, varscan2
- MFRP | chr11:119345614 A>C | 5'Flank (SNP) | VAF 9/54 reads (17%) | catalogued as COSV64128881; called by muse, mutect2, varscan2
- MIR548M | n.74C>A | RNA (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- RPL26P30 | n.949G>C | RNA (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2
- SLC47A1 | c.921+1629C>G | Intron (SNP) | VAF 10/101 reads (10%) | catalogued as COSV54503991, COSV99565282; called by muse, mutect2, varscan2
- TTN | c.10360+4789G>A | Intron (SNP) | VAF 48/115 reads (42%) | catalogued as rs933453861, COSV60199723; called by muse, mutect2, varscan2
- TTN | c.10360+1440C>A | Intron (SNP) | VAF 19/125 reads (15%) | catalogued as COSV60199726; called by muse, mutect2, varscan2
